Somatic mutation profile of tumor specimen TARGET-10-PARRSR-09A (aliquot TARGET-10-PARRSR-09A-01D) from TARGET case TARGET-10-PARRSR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.7 years (5,018 days).
Specimen TARGET-10-PARRSR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 528b74c6-f040-4e03-aa21-bf095b4d2aa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARRSR-10A (Blood Derived Normal), aliquot TARGET-10-PARRSR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9521a42a-a9cd-4f84-8420-9702d9ec6646

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- DYNC1H1 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.392); catalogued as rs767680991; called by muse, mutect2, varscan2
- FIP1L1 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as rs762022542; called by muse, mutect2, varscan2
- OR5M3 | c.370A>T p.I124F | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV56566218; called by muse, mutect2, varscan2
- UNC5A | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs749730825, COSV52839070; called by muse, mutect2, varscan2
- ZEB2 | c.3113A>G p.H1038R | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57953045; called by muse, mutect2, varscan2
- AMPD1 | c.1779-1G>A p.X593_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- FAM214A | c.2325A>T p.Q775H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.332); called by muse, mutect2
- MMS19 | c.1141G>T p.A381S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- SRP54 | c.1334A>G p.D445G | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ATRX | c.5574C>A p.G1858= | Silent (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- CHRDL2 | c.438C>T p.G146= | Silent (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- SNRPN | c.630G>A p.G210= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs1221130626; called by muse, mutect2, varscan2
- ZAN | c.1749G>A p.K583= | Silent (SNP) | VAF 63/149 reads (42%) | called by muse, mutect2, varscan2
- RBFOX3 | c.937-1698C>T | Intron (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2
- REG1B | c.183+127C>T | Intron (SNP) | VAF 10/20 reads (50%) | catalogued as rs914101723; called by muse, mutect2
